Somatic mutation profile of tumor specimen C3N-00168-04 (aliquot CPT0020010009) from CPTAC case C3N-00168, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.5 years (17,349 days).
Specimen C3N-00168-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2fd7de4-f35e-4fc0-b250-37524d79f739.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00168-31 (Blood Derived Normal), aliquot CPT0020920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96f53d36-ccd8-45a7-9aba-13893dbdb0c0

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 5, Intron 3, Nonsense Mutation 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMXL1 | c.5510A>T p.H1837L | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as rs564680072; called by muse, mutect2
- EPHX2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867470047; called by muse, mutect2
- KDM3B | c.3343C>T p.R1115W | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287032605, COSV58692920; called by muse, mutect2
- KRT32 | c.862A>G p.N288D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV56785340; called by muse, mutect2, varscan2
- PDPN | c.329C>T p.T110M (on ENST00000621990; = p.T186M on NM_006474.4) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs368396279; called by muse, mutect2
- RNF133 | c.857G>A p.W286* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | catalogued as rs1224943125; called by muse, mutect2
- SLC4A10 | c.1127G>T p.G376V (on ENST00000446997 / NM_001354461.2; = p.G346V on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55763091; called by muse, mutect2
- ACTB | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 43/469 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- CHUK | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CUBN | c.865T>C p.C289R | Missense Mutation (SNP) | VAF 30/545 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DHFR2 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- HIVEP2 | c.2025G>A p.M675I | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- HOOK3 | c.858T>G p.N286K | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2
- IL21 | c.360+1G>C p.X120_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- ITGA2 | c.2726G>C p.S909T | Missense Mutation (SNP) | VAF 21/370 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- ITPR2 | c.4588A>C p.K1530Q | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2
- LSM2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 19/312 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- MAST3 | c.560T>A p.M187K | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MUC17 | c.11918C>A p.T3973K | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2
- NEGR1 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 28/389 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.3); called by muse, mutect2
- OR51I2 | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- OVCH1 | c.841T>A p.F281I | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- P3H3 | c.1850A>G p.D617G | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.9); called by muse, mutect2
- SEPTIN5 | c.380A>C p.D127A | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- SPNS1 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.213); called by muse, mutect2
- VCAM1 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- ZNF407 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- ZNF91 | c.2548G>T p.G850* | Nonsense Mutation (SNP) | VAF 9/210 reads (4%) | called by muse, mutect2
- NAV2 | c.2430G>A p.Q810= (on ENST00000396087 / NM_001244963.2; = p.Q787= on NM_145117.5) | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV62337380; called by muse, mutect2
- PTPRT | c.1620G>T p.G540= | Silent (SNP) | VAF 20/326 reads (6%) | catalogued as COSV61961508; called by muse, mutect2
- SORBS2 | c.846G>T p.V282= (on ENST00000284776 / NM_021069.5; = p.V375= on NM_003603.6) | Silent (SNP) | VAF 27/264 reads (10%) | called by muse, mutect2, varscan2
- SPPL2B | c.804G>A p.A268= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs1032235271; called by muse, mutect2
- ZFAND3 | c.441T>C p.S147= | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- LHX8 | c.995-47T>A | Intron (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- MIR522 | n.65C>G | RNA (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- NALCN | c.2118+16del | Intron (DEL) | VAF 15/119 reads (13%) | called by mutect2, pindel, varscan2
- NDUFC2-KCTD14 | c.311-21440C>T | Intron (SNP) | VAF 10/280 reads (4%) | catalogued as rs1440788637; called by muse, mutect2
